EXCEPTIONAL_RESPONDERS case ER-ABOT — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f4df622d-dab6-4f73-96b0-f82008b5f19a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1932; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: primary; Age at diagnosis: 80.1 years (29,249 days); Year of diagnosis: 2012; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 924 days (2.5 years); Days to best overall response: 588 days (1.6 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin; Days to treatment start: 19 days; Days to treatment end: 931 days (2.5 years).
   Treatment given: Therapeutic agents: Pemetrexed; Days to treatment start: 19 days; Days to treatment end: 131 days.

Follow-up (1 entry)
- Days to follow up: 924 days (2.5 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 924 days (2.5 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABOT-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABOT-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 80; Percent lymphocyte infiltration: 55; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 5.
